FM case AD273 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/09d96fc0-491a-4aae-a685-2758981e386f

Male, 23.7 years: Esthesioneuroblastoma (ICD-O-3 9522/3) of the autonomic nervous system; metastasis biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 100% (pathologist estimate recorded by GDC). Sample type: Metastatic.
